Somatic mutation profile of tumor specimen ALCH-B2QN-TTP1-A (aliquot ALCH-B2QN-TTP1-A-1-0-D-A77Z-36) from ALCHEMIST case ALCH-B2QN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.0 years (26,286 days).
Specimen ALCH-B2QN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf53f767-f0c1-4bfd-8f3c-6f196ae25624.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2QN-NB1-A (Blood Derived Normal), aliquot ALCH-B2QN-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e5e8fe1-e8f7-4c2a-a741-a451c2c3c546

The open-access MAF lists 51 somatic variants for this specimen: 32 protein-altering or splice-affecting, 15 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 15, Splice Region 2, Intron 2, In Frame Ins 1, Splice Site 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2310_2311insGGT p.D770_N771insG | In Frame Ins (INS) | VAF 49/249 reads (20%) | hotspot (GDC flag); catalogued as COSV51766421, COSV51769298, COSV51772603, COSV51772611, COSV51785587, COSV51800700, COSV51802530, COSV51822889, COSV51835502, COSV51850813, COSV51866095; called by mutect2, pindel, varscan2
- APTX | c.470C>G p.A157G | Missense Mutation (SNP) | VAF 15/319 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV58929619; called by muse, mutect2
- BAP1 | c.2015A>G p.D672G | Missense Mutation (SNP) | VAF 121/449 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56233321; called by muse, mutect2, varscan2
- C6orf132 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV59373826; called by muse, mutect2, varscan2
- CLK3 | c.1270G>C p.E424Q (on ENST00000395066 / NM_001130028.1; = p.E276Q on NM_003992.4) | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV59341094; called by muse, mutect2, varscan2
- GALNT11 | c.246T>A p.S82R | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1479728369; called by muse, mutect2
- GLI3 | c.2551G>A p.A851T | Missense Mutation (SNP) | VAF 48/562 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762464634; called by muse, mutect2
- GYPC | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 86/449 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs149925576, COSV52146013; called by muse, mutect2, varscan2
- LILRA6 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as rs1306742464; called by muse, mutect2
- MAGEA8 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs781942405; called by muse, mutect2
- MYH4 | c.3027G>T p.Q1009H | Missense Mutation (SNP) | VAF 47/574 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV55113057, COSV55117892; called by muse, mutect2
- PPM1J | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.483); catalogued as rs201204322; called by muse, mutect2, varscan2
- TCTN3 | c.1673G>T p.G558V | Missense Mutation (SNP) | VAF 15/342 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV56452174; called by muse, mutect2
- TNXB | c.5554G>T p.D1852Y (on ENST00000647633; = p.D1605Y on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64480050; called by muse, mutect2, varscan2
- TRMT1 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs200953948; called by muse, mutect2, varscan2
- VPS8 | c.4056G>A p.K1352= (on ENST00000625842 / NM_001349294.1; = p.K1350= on NM_015303.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 29/213 reads (14%) | catalogued as COSV54996111; called by muse, mutect2, varscan2
- CCDC146 | c.2054A>C p.K685T | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2
- FANCI | c.1584-6A>T | Splice Region (SNP) | VAF 17/377 reads (5%) | called by muse, mutect2
- GRAMD1B | c.296G>C p.S99T | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- GTF2B | c.940C>A p.P314T | Missense Mutation (SNP) | VAF 47/304 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- IMPA1 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IPO7 | c.1945T>G p.L649V | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- LMF1 | c.137C>A p.T46K | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LRRC71 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRSAM1 | c.1423-1G>C p.X475_splice | Splice Site (SNP) | VAF 10/258 reads (4%) | called by muse, mutect2
- NCAN | c.3919A>G p.K1307E | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PITX3 | c.7T>C p.F3L | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.899); called by muse, mutect2
- SETD1B | c.5649G>T p.M1883I | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- SHLD1 | c.433T>A p.F145I | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); called by muse, mutect2
- TMPRSS3 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 16/556 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRUB1 | c.322A>G p.K108E | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.173); called by muse, mutect2
- UBAP2L | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 65/434 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ARHGAP1 | c.624C>T p.R208= | Silent (SNP) | VAF 21/129 reads (16%) | catalogued as rs1461065213; called by muse, varscan2
- HS3ST2 | c.849C>T p.G283= | Silent (SNP) | VAF 54/298 reads (18%) | catalogued as rs947875343, COSV54458927; called by muse, mutect2, varscan2
- IL24 | c.75C>G p.A25= | Silent (SNP) | VAF 35/150 reads (23%) | called by muse, mutect2, varscan2
- IL36A | c.450T>C p.T150= | Silent (SNP) | VAF 51/351 reads (15%) | called by muse, mutect2, varscan2
- KIF1A | c.654C>T p.H218= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as rs751380608, COSV57483836; ClinVar: likely benign; called by muse, mutect2, varscan2
- METTL17 | c.519A>T p.A173= | Silent (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- MOV10L1 | c.2754G>A p.Q918= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as COSV99434084; called by muse, mutect2
- NEMP2 | c.81G>A p.A27= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as rs988804765; called by muse, mutect2
- NMNAT1 | c.714C>T p.Y238= | Silent (SNP) | VAF 14/294 reads (5%) | called by muse, mutect2
- NOTCH1 | c.1176C>G p.V392= | Silent (SNP) | VAF 16/458 reads (3%) | called by muse, mutect2
- PCDHGA2 | c.705G>C p.A235= | Silent (SNP) | VAF 55/293 reads (19%) | catalogued as COSV53900566, COSV53952335; called by muse, mutect2, varscan2
- PPP1CC | c.837A>G p.A279= | Silent (SNP) | VAF 39/271 reads (14%) | called by muse, mutect2, varscan2
- SPTB | c.4389C>T p.L1463= | Silent (SNP) | VAF 99/544 reads (18%) | called by muse, mutect2, varscan2
- ZNF317 | c.315C>T p.L105= | Silent (SNP) | VAF 33/214 reads (15%) | called by muse, mutect2, varscan2
- ZSCAN25 | c.1374C>T p.P458= | Silent (SNP) | VAF 79/310 reads (25%) | catalogued as rs770816128; called by muse, mutect2, varscan2
- BBS2 | c.1798-14T>C | Intron (SNP) | VAF 62/376 reads (16%) | called by muse, mutect2, varscan2
- DBNDD2 | c.571+15T>A | Intron (SNP) | VAF 21/312 reads (7%) | called by muse, mutect2
- INPP5F | c.-28G>A | 5'UTR (SNP) | VAF 15/97 reads (15%) | catalogued as rs779249196; called by muse, mutect2, varscan2
- TAF10 | c.*1037G>A | 3'UTR (SNP) | VAF 117/633 reads (18%) | called by muse, mutect2, varscan2
